Surgical pathology report (de-identified scan), TCGA case TCGA-18-5592, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-5592-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST4L Low Paratracheal
2. Lymph node: Right low paratracheal ST4R
3. Lymph node: Right up paratracheal ST2R
4. Lymph node: subcarinal ST7
5. Lymph node: left up paratracheal ST2L
6. Lymph node: left TB angle ST10L
7. Lymph node: interlobar ST11L
8. Lung: resection margin pulmonary artery LUL
9. Lymph node: left TB angle ST10L no.2
10. Lymph node: inf. pulm. ligament ST9
11. Lung: LUL with QS on tumour
12. Lymph node: subcarinal ST7
13. Lymph node: subcarinal ST7 no.2

DIAGNOSIS

1-5. Lymph nodes, biopsies (ST4L left low paratracheal, ST4R right lower paratracheal, ST2R right upper paratracheal, ST7 subcarinal, ST2L left upper paratracheal):

- Lymph nodes negative for malignancy (x5)

6. "Lymph node", resection (ST10L left TB angle):

- Fibroadipose tissue, negative for malignancy; no lymph nodes identified

7. Lymph nodes, resection (ST11L interlobar):

- Lymph nodes, negative for malignancy

8. Soft tissue, resection (left upper lobe pulmonary artery margin):

- Negative for malignancy

9,10. Lymph nodes, resections (ST10L left TB angle number 2, ST9 inferior pulmonary ligament):

[page 2 of 6]
- Lymph nodes negative for malignancy (x2)

11. Lung, resection (left upper lobe):

a) Moderately differentiated squamous cell carcinoma (pT3N0), with:
(see Comment)

i) Greatest tumour dimension = 3.5 cm

ii) Visceral and mediastinal pleural invasion present

iii) Lymph-vascular invasion not identified

iv) Resection margins negative for tumour (closest margin: 0.2
cm, mediastinal soft tissue - see Comment)

v) Four lymph nodes negative for malignancy (0/4)

b) Lung tissue with post-obstructive pneumonitis

2,13. Lymph nodes, resections (ST7 subcarinal, ST7 subcarinal no. 2):

- Lymph nodes negative for malignancy (x2)

SYNOPTIC DATA

Specimen Type:	Lobectomy
Laterality:	Left
Tumor Site:	LUL
Tumor Size:	Greatest dimension: 3.5 cm Additional dimensions: 3.4 x 3.0 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Pathologic Staging (pTNM):	pT3: Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without
metastasis	pN0: No regional lymph node
Margins:	PMX: Cannot be assessed
carcinoma	Margins uninvolved by invasive
closest margin: 2 mm	Distance of invasive carcinoma from
(mediastinal)	Specify margin: soft tissue
rect Extension of Tumor:	Mediastinal pleura

Status: complete

Page: 2 of 6

[page 3 of 6]
[REDACTED]

[REDACTED]

	Visceral pleura
Venous (Large Vessel) Invasion:	Absent
Arterial (Large Vessel) Invasion:	Absent
Small/Intermediate Blood Vessel Invasion:	Absent
Additional Pathologic Findings:	Inflammation (type):
post-obstructive pneumonitis	
Neoadjuvant Treatment:	Unknown
Extension of Tumor:	Visceral pleura

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

COMMENT

11. Sections of the tumour show a moderately differentiated squamous cell carcinoma that invades through the visceral pleura, with dense adhesions to overlying soft tissue. At this point, tumor cells are present in fibrous tissue very close to a large nerve bundle (<0.1 cm), identified by [REDACTED] as the vagus nerve, but invasion of the nerve itself is not identified. Tumor cells are present focally 0.2 cm from a soft tissue edge in this area, presumably representing a mediastinal soft tissue resection margin. Pathologic tumor stage is assessed as pT3N0 (AJCC TNM staging, 7th ed.), by virtue of mediastinal pleural invasion. Correlation with intraoperative findings is suggested.

[REDACTED]

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as " ST 4L low paratracheal ". Two lymph nodes measuring 0.5 cm in maximum dimension each, submitted in toto for frozen section.

1A frozen section block, resubmitted

2. The specimen is labeled with the patient's name and as "right lower paratracheal ST 4R ". Three lymph nodes measuring 0.3, 0.5 and 0.7 cm in maximum dimension each, submitted in toto for frozen section.

2A frozen section block, resubmitted

[page 4 of 6]
[REDACTED]

3. The specimen is labeled with the patient's name and as "right upper paratracheal ST 2R ". Three lymph nodes measuring 0.2, 0.3 and 0.4 cm in maximum dimension each, submitted in toto for frozen section.

3A frozen section block, resubmitted

4. The specimen is labeled with the patient's name and as "subcarinal ST 7 ". Three lymph nodes measuring 0.1, 0.2, 0.3 cm in maximum dimension each, submitted in toto for frozen section.

4A frozen section block, resubmitted

5. The specimen is labeled with the patient's name and as "left upper paratracheal ST 2L ". Four lymph nodes measuring 0.2, 0.2, 0.2 and 0.4 cm in maximum dimension each, submitted in toto for frozen section.

5A frozen section block, resubmitted

6. The specimen is labeled with the patient's name and as "left upper paratracheal ST 2L ". One piece of fatty tissue measuring 1.7 x 1.5 x 0.4 cm

6A- submitted in toto

7. The specimen is labeled with the patient's name and as "interlobar ST 11L ". Four pieces of black tissue measuring from 0.4 x 0.4 x 0.4 cm to 0.9 x 0.8 x 0.6 cm

7A- submitted in toto

8. The specimen container is labeled with the patient's name and as "Lung: Resection margin pulmonary artery LUL QS" consists of 4 pieces of tissue measuring from 0.2 to 0.4 cm in greatest dimension received fresh. This is examined at intraoperative consultation by frozen section performed on the entire specimen.

8A- frozen section block resubmitted.

9. The specimen container is labeled with the patient's name and as "Lymph Node: Left TB angle ST10L no. 2" consists of a piece of black-brown tissue measuring 2.2 x 1.5 x 0.8 cm received in 10% buffered formalin.

9A-9B- bisected and submitted in toto.

10. The specimen container is labeled with the patient's name and as "Lymph Node: Inferior pulmonary ligament ST9" consists of a piece of yellow-brown to gray-brown tissue measuring 2.7 x 1.6 x 1.2 cm received

[page 5 of 6]
in 10% buffered formalin.
10A-10B- bisected and submitted in toto.

11. The specimen container is labeled with the patient's identification and as "Lung: LUL with QS on tumor". It contains a lobectomy specimen measuring 21.0 x 12.5 x 3.5 cm. On external examination, the pleura is intact and shows surface adhesions, except for an area of puckering measuring 3.0 x 3.0 cm. On sectioning, a peripheral tumor is noted measuring 3.5 x 3.4 x 3.0 cm. The tumor puckers the pleura. The cut surface of the tumor is gray-tan in color and solid in consistency. It is 1.0 cm from the bronchial resection margin and 0.5 cm from the closest stapled parenchymal resection margin. Adjacent to the tumor is an ill-defined firm area and on sectioning reveals a lobulated yellow-tan appearance query area of consolidation measuring 3.0 x 2.8 cm. The rest of the cut surface of the lung parenchyma is grossly unremarkable. No other nodules or masses are identified. Multiple peribronchial lymph nodes are identified ranging in size from 1.0 x 0.8 x 0.6 cm to 1.7 x 0.8 x 0.4 cm. A section of tumor is submitted for frozen section.

Representative sections are submitted as follows:

11A -frozen section block resubmitted.

11B- bronchial resection margin en face adjacent to the stapled bronchial margin.

11C-multiple peribronchial lymph nodes

11D-11I-tumor in relation to pleura

11J-11L-adjacent area of consolidation

11M-11N-normal lung tissue away from the tumor

Four pieces of tumor/normal are stored frozen.

12. The specimen container is labeled with the patient's name and as "Lymph Node: Subcarinal ST7" consists of 3 pieces of black-brown and a gray-yellow tissue measuring from 0.7 x 0.5 x 0.5 cm to 1.5 x 1.0 x 1.0 cm received in 10% buffered formalin.

12A-12C-each piece is bisected and submitted in toto.

13. The specimen container is labeled with the patient's name and as "Lymph Node: Subcarinal ST7 no.2" consists of a piece of black-brown tissue measuring 1.7 x 0.8 x 0.4 cm received in 10% buffered formalin

13A- bisected and submitted in toto.

[page 6 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

1 - 5. Lymph-Nodes: ST4L Low Paratracheal, ST4R Low Paratracheal, RT UP
Paratracheal ST2R, Subcarinal ST7, Lt Up Paratracheal ST 2 L :
Negative for malignancy

8. Resection margin, pulmonary artery, LUL:
Negative for malignancy

11. Left upper lobe:
Squamous cell carcinoma

[REDACTED]

Source: NCI Genomic Data Commons file 4d50f68d-0149-4aee-b213-f80e9319ae91 (TCGA-18-5592.FE921521-1681-4F88-BCDA-B216CEA7981A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).